Surgical pathology report (de-identified scan), TCGA case TCGA-BR-7958, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-7958-01A (Primary Tumor).

[page 1 of 4]
[REDACTED] ID		Gross Description	Microscopic Description
Case ID			
[REDACTED]	[REDACTED]		

[page 2 of 4]
Diagnosis Details	Comments

[page 3 of 4]
Formatted Path Report

STOMACH TISSUE CHECKLIST

Specimen type: Excision of tumor

Tumor site: Fundus

Tumor size: 3.5 x 3 x 1 cm

Tumor features: None specified

Histologic type: Adenocarcinoma

Histologic grade: Poorly differentiated

Tumor extent: Adjacent structures (specify) - Lesser omentum

Lymph nodes: 0/4 positive for metastasis (Regional 0/4)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Perineural invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Laterality

[page 4 of 4]
Excision date

© 2004 Blackwell Publishing Ltd

Source: NCI Genomic Data Commons file 2488a3e2-138e-4a68-a36a-8e072c68e634 (TCGA-BR-7958.CA979CE5-E9A0-4816-83CC-BC2F169D00DE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).